Somatic mutation profile of tumor specimen TCGA-19-A6J5-01A (aliquot TCGA-19-A6J5-01A-21D-A33T-08) from TCGA case TCGA-19-A6J5, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 41.0 years (14,970 days).
Specimen TCGA-19-A6J5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e654b54-6761-48d1-af32-e9618055f53c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-A6J5-10A (Blood Derived Normal), aliquot TCGA-19-A6J5-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4bc11add-ec18-4fc3-a77c-7a380e63d12f

The open-access MAF lists 51 somatic variants for this specimen: 37 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 12, Nonsense Mutation 3, 5'UTR 1, Splice Site 1, Frame Shift Ins 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 35/62 reads (56%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 61/64 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALDH6A1 | c.1377A>T p.K459N | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV100620771; called by muse, mutect2, varscan2
- ANKRD36B | c.879A>C p.K293N | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as COSV99307755; called by muse, mutect2, varscan2
- ASTL | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs146799484; called by muse, mutect2, varscan2
- ATRX | c.2868del p.V957Yfs*13 | Frame Shift Del (DEL) | VAF 84/130 reads (65%) | catalogued as CD151220; called by mutect2, pindel, varscan2
- CBX4 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as COSV99490141; called by muse, mutect2, varscan2
- CERS6 | c.1022G>C p.S341T | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99986363; called by muse, mutect2, varscan2
- CMTR2 | c.2053G>T p.V685F | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV100578936; called by muse, mutect2, varscan2
- CRISP2 | c.515+1G>A p.X172_splice | Splice Site (SNP) | VAF 37/76 reads (49%) | catalogued as rs147611117; called by mutect2, varscan2
- DDC | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 80/290 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs752474261, COSV63567513; called by muse, mutect2, varscan2
- DNAAF5 | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 101/179 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as rs746765259, COSV52414987; called by muse, mutect2, varscan2
- DOCK6 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1161991286, COSV99370835; called by muse, mutect2
- EDC4 | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100738763; called by muse, mutect2, varscan2
- EIF2B5 | c.2116C>T p.R706C (on ENST00000647909; = p.R698C on NM_003907.3) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs374599117, COSV56606256; called by muse, mutect2, varscan2
- ERBB4 | c.457A>G p.K153E | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as COSV99614574; called by muse, mutect2, varscan2
- GLRA4 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 92/96 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65456508; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.344G>T p.C115F | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs748164842; called by muse, mutect2, varscan2
- IMPACT | c.71G>C p.G24A | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV99408741; called by muse, mutect2, varscan2
- INO80 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.296); catalogued as COSV100731491; called by muse, mutect2, varscan2
- KIR3DL3 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 8/232 reads (3%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1373837445; called by muse, mutect2
- MYH11 | c.4091G>A p.R1364H | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs747473469, COSV100257368; called by muse, mutect2, varscan2
- MYO1F | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs774694675, COSV57801160; called by muse, mutect2, varscan2
- NKD2 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.201); catalogued as rs745548994, COSV99723680; called by muse, mutect2, varscan2
- PIAS2 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs116577469, COSV100244881; called by muse, mutect2, varscan2
- POLQ | c.2579G>A p.R860Q | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs1365547447, COSV51745479; called by muse, mutect2, varscan2
- PTEN | c.583T>A p.F195I | Missense Mutation (SNP) | VAF 54/59 reads (92%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.621); catalogued as COSV100909195, COSV64308038; called by muse, mutect2, varscan2
- RBM25 | c.1789C>T p.R597* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99998310; called by muse, mutect2, varscan2
- RFX6 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1229596530, COSV60586224, COSV60589902; called by muse, mutect2, varscan2
- SCAF11 | c.2119A>T p.K707* | Nonsense Mutation (SNP) | VAF 57/123 reads (46%) | catalogued as COSV101014012; called by muse, mutect2, varscan2
- SEC16A | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV99255676; called by muse, mutect2, varscan2
- SLC7A5 | c.1015G>A p.V339I | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as rs749906196, COSV55363192; called by muse, mutect2, varscan2
- ST14 | c.1887G>T p.Q629H | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99598393; called by muse, mutect2, varscan2
- TMCO5A | c.459T>G p.Y153* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100148388; called by muse, mutect2, varscan2
- TTBK2 | c.982A>C p.I328L | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.342); catalogued as COSV99141039; called by muse, mutect2, varscan2
- ZFP42 | c.323A>G p.Q108R | Missense Mutation (SNP) | VAF 36/43 reads (84%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV100478536; called by muse, mutect2, varscan2
- RGS6 | c.552dup p.D185Rfs*10 | Frame Shift Ins (INS) | VAF 54/150 reads (36%) | called by mutect2, pindel, varscan2
- BRIX1 | c.985T>C p.L329= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV100331248, COSV57760799; called by muse, mutect2
- C1orf158 | c.168C>A p.P56= | Silent (SNP) | VAF 41/44 reads (93%) | catalogued as COSV99847145; called by muse, mutect2, varscan2
- CLEC2B | c.309A>G p.G103= | Silent (SNP) | VAF 32/60 reads (53%) | catalogued as COSV99946883; called by muse, mutect2, varscan2
- FCGBP | c.6594C>T p.R2198= | Silent (SNP) | VAF 38/441 reads (9%) | catalogued as rs767491514, COSV99660383; called by muse, mutect2
- HEMGN | c.963T>A p.P321= | Silent (SNP) | VAF 68/244 reads (28%) | catalogued as rs941157663, COSV99412251; called by muse, mutect2, varscan2
- IGHM | c.363C>T p.D121= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs781904232; called by muse, mutect2, varscan2
- MYH14 | c.783A>G p.R261= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99221443; called by muse, mutect2, varscan2
- SLC24A1 | c.1473C>T p.S491= | Silent (SNP) | VAF 41/99 reads (41%) | catalogued as rs557624344, COSV99977965; called by muse, mutect2, varscan2
- SMARCAL1 | c.375C>T p.P125= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as COSV100619698, COSV61920725; called by muse, mutect2, varscan2
- TTLL4 | c.3387C>T p.D1129= | Silent (SNP) | VAF 57/133 reads (43%) | catalogued as rs772350700, COSV51434839; called by muse, mutect2, varscan2
- UNC13D | c.1500C>T p.G500= | Silent (SNP) | VAF 59/131 reads (45%) | catalogued as rs199672701; called by muse, mutect2, varscan2
- ZDBF2 | c.4671C>T p.V1557= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV100984272; called by muse, mutect2, varscan2
- CNOT6L | c.-98_-69del | 5'UTR (DEL) | VAF 16/54 reads (30%) | called by mutect2, pindel
- ZNF226 | c.236-495T>C | Intron (SNP) | VAF 25/30 reads (83%) | catalogued as COSV100334987; called by muse, mutect2, varscan2
